Gene-level copy-number profile of tumor specimen TCGA-XF-AAMQ-01A from TCGA case TCGA-XF-AAMQ, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage II; Tumor grade: High Grade; Age at diagnosis: 59.3 years (21,660 days).
Specimen TCGA-XF-AAMQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.43fbde3e-3d56-45f1-afc6-a64c6a661500.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XF-AAMQ-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5dd735fd-2eca-4dc4-ac24-55f26bc48b10

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 456; copy number 2: 8,780; copy number 3: 24,928; copy number 4: 18,845; copy number 5: 6,530; copy number 6: 63; copy number 7: 95; copy number 8: 19; copy number 9: 37; copy number 10: 24; copy number 14: 1; copy number 22: 6; copy number 23: 9; copy number 24: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XF-AAMQ-01A-11D-A42D-01): tumor purity 0.7, ploidy 3.28, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,858,910–23,682,662, 22 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1, AL357614.1, AL445623.2, SUMO2P2, AL445623.1, NOP56P2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 193 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:37,326,575–40,897,833, 88 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr11:69,294,151–69,819,416, 15 genes, copy number 22–23: MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3.
- chr11:69,985,876–70,021,059, 2 genes, copy number 24: AP003555.2, AP003555.1.
- chr11:70,477,277–70,477,592, 1 gene, copy number 14: AP001271.1.
- chr17:20,710,425–21,641,536, 43 genes, copy number 8–10: AC087499.6, AC087499.2, RNFT1P3, HNRNPA1P19, OLA1P2, SCDP1, AC126365.1, AC126365.2, ABHD17AP6, CCDC144NL, AC090774.2, CCDC144NL-AS1, RNU6-1178P, RNASEH1P1, AC090774.1, SPECC1P2, AC107926.1, AC087393.3, AC087393.1, USP22, AC087393.2, LINC01563, DHRS7B, TMEM11, AC087294.1, RN7SL426P, NATD1, EIF1P5, MAP2K3, KCNJ12, LINC02693, AC068418.3, PDLIM1P2, AC068418.2, AC068418.1, RPL21P120, AC233702.5, AC233702.7, AC233702.8, AC233702.6, AC233702.3, AC233702.2, AC233702.1.
- chr20:472,498–610,398, 2 genes, copy number 7 (within-gene range 3–7): CSNK2A1, TCF15.
- chr20:833,715–1,118,467, 5 genes, copy number 7 (within-gene range 3–7): FAM110A, RPS10P5, ANGPT4, RSPO4, AL110114.1.
- chr20:31,514,410–32,335,011, 37 genes, copy number 9 (within-gene range 3–9): HM13, AL110115.1, MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P, ID1, MIR3193, COX4I2, BCL2L1, BCL2L1-AS1, ABALON, TPX2, AL160175.1, MYLK2, FOXS1, DUSP15, TTLL9, RNU1-94P, PDRG1, XKR7, AL031658.2, AL031658.1, RNA5SP481, CCM2L, RNA5SP482, HCK, TM9SF4, AL049539.1, RSL24D1P6, TSPY26P, PLAGL2, POFUT1, MIR1825, AL121897.1, KIF3B.

Autosomal genes at a single copy (total copy number 1): 456. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
